Somatic mutation profile of tumor specimen TCGA-UD-AABZ-01A (aliquot TCGA-UD-AABZ-01A-12D-A39R-32) from TCGA case TCGA-UD-AABZ, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 46.3 years (16,913 days).
Specimen TCGA-UD-AABZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e77e79e2-a49f-43a9-8433-040093bcc581.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UD-AABZ-10A (Blood Derived Normal), aliquot TCGA-UD-AABZ-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a70dd26-c613-4ed6-a527-bbd6d5ab9197

The open-access MAF lists 35 somatic variants for this specimen: 29 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 5, Nonsense Mutation 3, Frame Shift Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP2 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs755507497; called by muse, mutect2, varscan2
- AP1M2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372188688; called by muse, mutect2, varscan2
- ATM | c.5435C>G p.A1812G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as CD982460, COSV53742238; called by muse, varscan2
- COL7A1 | c.5105C>T p.P1702L | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1270080886; called by muse, mutect2
- CR1 | c.3787G>T p.G1263C | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as COSV65458594; called by muse, mutect2, varscan2
- EPPK1 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 55/151 reads (36%) | catalogued as rs781917927; called by muse, mutect2, varscan2
- MMP20 | c.1020C>A p.F340L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV52774081, COSV99497939; called by muse, mutect2, varscan2
- NF2 | c.363+1G>C p.X121_splice | Splice Site (SNP) | VAF 3/29 reads (10%) | catalogued as CS982285, COSV58520817, COSV58521527, COSV58527414; called by muse, mutect2
- NPR1 | c.2122C>G p.R708G | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV64117335; called by muse, mutect2, varscan2
- OCM2 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 14/88 reads (16%) | catalogued as COSV57535530; called by muse, mutect2, varscan2
- POLD2 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450724038; called by muse, mutect2, varscan2
- PTPN4 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as rs200544847; called by muse, mutect2, varscan2
- SOX1 | c.1166C>A p.T389K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV58378693; called by muse, mutect2, varscan2
- SOX11 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1349218134; called by muse, mutect2, varscan2
- C1QBP | c.143T>A p.V48E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CARD6 | c.1418C>T p.T473I | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- DNAH3 | c.7479C>A p.D2493E | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRRS1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- HRNR | c.320A>G p.Q107R | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IL11RA | c.176G>A p.W59* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- INTS4 | c.2653C>A p.P885T | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); called by muse, mutect2
- MTUS2 | c.1739T>C p.L580S | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- MYH6 | c.3274C>A p.Q1092K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NEXMIF | c.3788A>T p.Q1263L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PDZD2 | c.4259G>T p.R1420I | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PDZRN3 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PPTC7 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPEM2 | c.9C>A p.N3K | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- TTK | c.1494dup p.L499Tfs*18 | Frame Shift Ins (INS) | VAF 32/186 reads (17%) | called by mutect2, pindel, varscan2
- CHD2 | c.249A>G p.K83= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs990673547, COSV100560839; called by muse, mutect2, varscan2
- EDIL3 | c.1098C>T p.A366= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2
- GALNT13 | c.1014C>T p.C338= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as rs1007111459; called by muse, mutect2, varscan2
- RXRB | c.1242A>T p.G414= | Silent (SNP) | VAF 44/132 reads (33%) | called by muse, mutect2, varscan2
- TRIM40 | c.537G>C p.L179= (on ENST00000376724; = p.L150= on NM_138700.4) | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- NCOA7 | c.2245-1635G>A | Intron (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
